Gene-level copy-number profile of tumor specimen TCGA-42-2589-01A from TCGA case TCGA-42-2589, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.4 years (19,852 days).
Specimen TCGA-42-2589-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5528ed94-763e-4543-acda-16194c6172cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-42-2589-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fbb00bf4-17dc-4847-a8db-0b8b0bc4a3c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 140; copy number 1: 23,186; copy number 2: 29,451; copy number 3: 6,070; copy number 4: 521; copy number 5: 448.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-42-2589-01A-01D-1043-01): tumor purity 0.85, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:36,521,721–36,524,234, 1 gene: NAMPTP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 448 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,861,599–204,377,665, 18 genes, copy number 5 (within-gene range 3–5): SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1.
- chr4:3,889,356–6,884,170, 64 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:122,311,354–122,464,219, 1 gene, copy number 5 (within-gene range 2–5): SNCAIP.
- chr5:122,369,762–122,479,087, 3 genes, copy number 5: AC119150.1, AC119150.2, MGC32805.
- chr8:127,253,213–145,066,685, 339 genes, copy number 5 (broad region; genes not listed).
- chr11:33,880,643–35,232,402, 23 genes, copy number 5 (within-gene range 2–5): AC132216.1, AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1.

Autosomal genes at a single copy (total copy number 1): 21,904. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
